TARGET case TARGET-40-NAAWGK — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms.
https://portal.gdc.cancer.gov/cases/4718fc65-4cca-56d9-bcbb-d07257a6102e

Biospecimens (1 sample)
- Sample TARGET-40-NAAWGK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
